Somatic mutation profile of tumor specimen TCGA-86-8671-01A (aliquot TCGA-86-8671-01A-11D-2393-08) from TCGA case TCGA-86-8671, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.4 years (26,448 days).
Specimen TCGA-86-8671-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a49bae8-1052-4ade-94eb-843842910c24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8671-10A (Blood Derived Normal), aliquot TCGA-86-8671-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e62aaf6b-abf9-4129-9e80-a576432b0437

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4672T>C p.C1558R | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100710330; called by muse, mutect2
- ADAR | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as COSV99425542; called by muse, mutect2
- ANAPC5 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.152); catalogued as COSV99945955; called by muse, mutect2
- ASPM | c.9128A>T p.Y3043F | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.147); catalogued as COSV99659619; called by muse, mutect2
- ATAD5 | c.4408T>G p.S1470A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV100429686, COSV58971667, COSV58976975; called by muse, mutect2
- BRWD3 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | catalogued as COSV100955674, COSV100956136; called by muse, mutect2
- CD40LG | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV101033433; called by muse, mutect2
- CNTNAP5 | c.591G>C p.L197F | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.117); catalogued as COSV101443091; called by muse, mutect2
- EDEM1 | c.1581C>A p.V527= | Splice Region (SNP) | VAF 7/88 reads (8%) | catalogued as COSV56583450, COSV99849031; called by muse, mutect2
- EPHA8 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51269410; called by muse, mutect2
- FANCB | c.1760T>C p.L587P | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100146399; called by muse, mutect2
- FZD10 | c.1710A>C p.K570N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99969264; called by muse, mutect2, varscan2
- HERC6 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as COSV99910454; called by muse, mutect2
- NYNRIN | c.1576C>G p.Q526E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as COSV101230509, COSV101230522; called by muse, mutect2
- OR4K2 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100064156, COSV53850349; called by muse, mutect2
- OR8B8 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV60143936; called by muse, mutect2
- PCDHGB2 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.461); catalogued as COSV99531611, COSV99543588; called by muse, mutect2
- PHKA2 | c.2903G>T p.R968I | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV101176708; called by muse, mutect2
- PIK3R4 | c.1183A>G p.K395E | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100768253; called by muse, mutect2
- PMFBP1 | c.1770T>G p.N590K (on ENST00000537465; = p.N585K on NM_031293.3) | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as COSV99400278; called by muse, mutect2
- PYCR1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1053110486, COSV58000259; called by muse, mutect2
- SMARCC2 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs144543721; called by muse, mutect2
- TLDC2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV99455729; called by muse, mutect2
- VCAN | c.5810A>G p.D1937G | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99424826; called by muse, mutect2
- ZNF652 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV100755549; called by muse, mutect2
- ATP10A | c.2463A>G p.E821= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV100790922; called by muse, mutect2
- CD36 | c.351C>G p.P117= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99987207; called by muse, mutect2
- FAM47C | c.1446C>T p.D482= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100792207; called by muse, mutect2
- GALNT6 | c.987C>T p.F329= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as rs1456773357, COSV100695316; called by muse, mutect2
- SBK1 | c.78T>A p.G26= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100543404; called by muse, mutect2
- SESTD1 | c.882A>G p.E294= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as COSV58931215; called by muse, mutect2
- TRPC4AP | c.204A>G p.Q68= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs746988790, COSV99327848; called by muse, mutect2, varscan2
- VPS13A | c.8097A>G p.S2699= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100652212; called by muse, mutect2, varscan2
